Surgical pathology report (de-identified scan), TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0152-02A (Recurrent Tumor).

PATIENT NAME:

AGE/SEX:

M

ACC. NO.:

ORDERING PHYSICIAN:

PATH. NO:

NAME:

MED. REC. NO:

AGE/SEX:

M

DOB:

SURGERY DATE:

PHYSICIAN:

RECEIVE DATE:

PATHOLOGICAL DIAGNOSIS:

1CA-0-3

BRAIN BIOPSY:

1. GLIOBLASTOMA.

2. RADIATION EFFECT.

glioblastoma, multiforme 9440/3
Site: brain, NOS C 71.9

hw
2/17/15

Operation/Specimen:

Clinical History and Pre-Op Dx: Recurrent tumor.

GROSS PATHOLOGY: The specimen labeled "recurrent tumor", are multiple 0.5 to 2.5 cm. gray-white to tan tissue. Representative sections submitted in cassettes 1-5.

MICROSCOPIC: Sections reveal a glioblastoma with characteristic disading necrosis. Also noted are changes consistent with radiation effect, such as coagulation necrosis, gliosis, sclerotic vessels and aggregates of macrophages. The proliferative index as measured by the MIB-1 stain is about 25%.

TISSUE COMMITTEE CODE:

BILLING CODES:

Source: NCI Genomic Data Commons file 091eb1f7-b412-40aa-97db-6a6799b8c1fc (TCGA-06-0152.DBD8D383-7A03-4A1B-B665-BDAF66C743E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).